Somatic mutation profile of tumor specimen TCGA-NJ-A4YI-01A (aliquot TCGA-NJ-A4YI-01A-11D-A25L-08) from TCGA case TCGA-NJ-A4YI, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 87.2 years (31,867 days).
Specimen TCGA-NJ-A4YI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fe36903-14d0-481a-af5f-b50b10327bba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NJ-A4YI-10A (Blood Derived Normal), aliquot TCGA-NJ-A4YI-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb3743c1-f5ac-4003-8fe3-7b6170dfbc78

The open-access MAF lists 502 somatic variants for this specimen: 376 protein-altering or splice-affecting, 115 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 312, Silent 115, Nonsense Mutation 26, Splice Site 15, Frame Shift Del 14, Intron 4, Frame Shift Ins 4, RNA 4, In Frame Del 3, 3'UTR 2, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 19/31 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASS | c.1407-2A>T p.X469_splice | Splice Site (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100741867; called by mutect2, varscan2
- ABCB5 | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99329370; called by muse, mutect2, varscan2
- ABCG5 | c.1463+1G>T p.X488_splice | Splice Site (SNP) | VAF 13/53 reads (25%) | catalogued as COSV99575595; called by muse, mutect2, varscan2
- ABR | c.1486G>T p.D496Y (on ENST00000302538 / NM_021962.5; = p.D459Y on NM_001092.5) | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99348500; called by muse, mutect2
- ACSS3 | c.1039G>C p.G347R | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99699372; called by muse, mutect2, varscan2
- ACTBL2 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101379411; called by muse, mutect2, varscan2
- ADAM12 | c.2635C>A p.Q879K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100903512, COSV64127240; called by muse, mutect2, varscan2
- ADAMTS2 | c.2834C>A p.P945Q | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as rs200309353, COSV99283670; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2450C>A p.T817K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.068); catalogued as COSV54446229, COSV99720858; called by muse, mutect2, varscan2
- ADCY10 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100897055; called by muse, mutect2, varscan2
- ADCY2 | c.2262C>A p.F754L | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV57905630; called by muse, mutect2, varscan2
- ADCY2 | c.2263C>A p.L755M | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100603907; called by muse, mutect2, varscan2
- ADGRL1 | c.3896C>T p.A1299V (on ENST00000340736 / NM_001008701.3; = p.A1294V on NM_014921.5) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs375409399; called by muse, mutect2, varscan2
- ADHFE1 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99398129; called by muse, mutect2, varscan2
- AFF1 | c.847A>T p.S283C | Missense Mutation (SNP) | VAF 98/213 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100321009; called by muse, mutect2, varscan2
- AHNAK | c.10258G>T p.V3420L | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV99949311; called by muse, mutect2, varscan2
- ALDH4A1 | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99312272; called by muse, mutect2, varscan2
- AMER2 | c.1886C>A p.P629H | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100766366, COSV63437634; called by muse, mutect2, varscan2
- ANGPTL2 | c.522C>A p.S174R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV99402470; called by muse, mutect2, varscan2
- ANGPTL3 | c.552C>A p.D184E | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52016367; called by muse, mutect2, varscan2
- ANKDD1A | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as rs766001684, COSV100132750, COSV60354411; called by muse, mutect2, varscan2
- ANKRD52 | c.2195G>C p.G732A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV99921568; called by muse, mutect2, varscan2
- ANKS3 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100423258; called by muse, mutect2, varscan2
- AQR | c.2964A>T p.E988D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99334562; called by muse, mutect2, varscan2
- ARFIP2 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99601657; called by muse, mutect2, varscan2
- ARNT2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1326668677, COSV57585005; called by muse, mutect2, varscan2
- ASXL3 | c.3079A>T p.S1027C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99326266; called by muse, mutect2, varscan2
- ASXL3 | c.4543G>C p.A1515P | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV99326267; called by muse, mutect2, varscan2
- ASXL3 | c.5821C>A p.P1941T | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV99326269; called by muse, mutect2, varscan2
- ATF7IP | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 46/78 reads (59%) | catalogued as COSV53770608; called by muse, mutect2, varscan2
- AVPR1A | c.1046T>A p.M349K | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1239455732, COSV100146899; called by muse, varscan2
- AVPR1A | c.986C>A p.T329N | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV100146901; called by muse, varscan2
- AXIN2 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.38); catalogued as rs751143605, COSV100196902; ClinVar: uncertain significance; called by muse, mutect2
- BDP1 | c.1391G>C p.R464T | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100703459, COSV62432641; called by muse, mutect2, varscan2
- BEND6 | c.24T>A p.D8E | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV100876950; called by muse, mutect2, varscan2
- BEST4 | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100944039; called by muse, mutect2, varscan2
- BICRAL | c.1444G>T p.G482* | Nonsense Mutation (SNP) | VAF 73/163 reads (45%) | catalogued as COSV100018416; called by muse, mutect2, varscan2
- BPTF | c.6835A>G p.T2279A | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV100075880; called by muse, mutect2, varscan2
- BTBD17 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as COSV100945395; called by muse, mutect2, varscan2
- C11orf65 | c.228+1G>A p.X76_splice | Splice Site (SNP) | VAF 24/75 reads (32%) | catalogued as rs777589305, COSV101262889; called by muse, mutect2, varscan2
- CACNA1B | c.4425C>A p.Y1475* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV99499394; called by muse, mutect2, varscan2
- CACNA1I | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100361365; called by muse, mutect2, varscan2
- CDC20B | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99696832; called by muse, mutect2, varscan2
- CELSR3 | c.5284G>A p.A1762T | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99374761; called by muse, mutect2, varscan2
- CFAP52 | c.1735G>C p.V579L | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV99557012; called by muse, mutect2, varscan2
- CFAP69 | c.2782G>T p.A928S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV100290404; called by muse, mutect2, varscan2
- CHD4 | c.1366T>C p.S456P (on ENST00000357008 / NM_001363606.2; = p.S469P on NM_001273.5) | Missense Mutation (SNP) | VAF 73/120 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100539065; called by muse, mutect2, varscan2
- CNTNAP2 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV62140241, COSV62213628; called by muse, mutect2, varscan2
- CNTNAP2 | c.1778-1G>T p.X593_splice | Splice Site (SNP) | VAF 23/91 reads (25%) | catalogued as COSV100671118; called by muse, mutect2, varscan2
- COL22A1 | c.969G>T p.Q323H | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57370205; called by muse, mutect2, varscan2
- COL6A2 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as COSV100153741, COSV100154142; called by muse, mutect2, varscan2
- COL6A2 | c.1808G>T p.G603V | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100154143; called by muse, mutect2, varscan2
- COPA | c.696G>T p.W232C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99616656; called by muse, mutect2, varscan2
- CP | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99224411; called by muse, mutect2, varscan2
- CPM | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 26/138 reads (19%) | catalogued as COSV100615251; called by muse, mutect2, varscan2
- CPNE3 | c.879+1G>T p.X293_splice | Splice Site (SNP) | VAF 14/26 reads (54%) | catalogued as COSV99548034; called by muse, mutect2, varscan2
- CRACD | c.3220G>T p.D1074Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99949915; called by muse, mutect2, varscan2
- CROCC | c.5158A>G p.S1720G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0.078); catalogued as COSV100978384; called by muse, mutect2, varscan2
- CS | c.1315A>T p.S439C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100370023; called by muse, mutect2, varscan2
- CSNK1G2 | c.1105G>T p.G369W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99730181; called by muse, mutect2, varscan2
- CTNND2 | c.3394G>T p.A1132S | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100480534; called by muse, mutect2, varscan2
- CUX2 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99920601; called by muse, mutect2, varscan2
- CYP24A1 | c.612C>A p.Y204* | Nonsense Mutation (SNP) | VAF 33/120 reads (28%) | catalogued as COSV99398553; called by muse, mutect2, varscan2
- CYP26C1 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53653770; called by muse, mutect2, varscan2
- CYP2A13 | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100386994; called by muse, mutect2, varscan2
- CYP4A11 | c.1367A>T p.N456I | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100152604; called by muse, mutect2
- CYP4B1 | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as rs765862813, COSV54726059, COSV99597430; called by muse, mutect2, varscan2
- CYTIP | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV51632261, COSV51633302; called by muse, mutect2, varscan2
- DCAF4L2 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV60478355; called by muse, mutect2, varscan2
- DDN | c.1191T>A p.H397Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV100305397; called by muse, mutect2, varscan2
- DMKN | c.203G>T p.S68I | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as rs1316252979, COSV100303913; called by muse, mutect2, varscan2
- DNAH17 | c.279G>T p.R93S | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.091); catalogued as rs375879842, COSV101103254; called by muse, mutect2, varscan2
- DNAH3 | c.3428C>T p.A1143V | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99770196; called by muse, mutect2, varscan2
- DPY19L2 | c.953G>T p.R318M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100116949; called by muse, mutect2
- DPY19L3 | c.482A>C p.Y161S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.995); catalogued as COSV100639287; called by muse, mutect2, varscan2
- DPYSL5 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761738108, COSV99982736; called by muse, mutect2, varscan2
- DRD1 | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101192517; called by muse, mutect2, varscan2
- DRD5 | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100432001; called by muse, mutect2, varscan2
- DRP2 | c.2025C>A p.N675K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100872045; called by muse, mutect2, varscan2
- DSC2 | c.1080T>A p.Y360* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV99199845; called by muse, mutect2, varscan2
- DSG3 | c.1475G>C p.C492S | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57127402, COSV57127512; called by muse, mutect2, varscan2
- DYNC1H1 | c.12638G>T p.R4213L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100795328, COSV64134558; called by muse, mutect2, varscan2
- DYRK1A | c.965T>G p.I322S | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100118239; called by muse, mutect2, varscan2
- EBF1 | c.806C>A p.P269Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565887, COSV100566474, COSV58177454; called by muse, mutect2, varscan2
- EHD2 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV54408195, COSV99622191; called by muse, mutect2, varscan2
- ENPP7 | c.951G>T p.E317D | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV100093664; called by muse, mutect2, varscan2
- EPHA6 | c.1049G>T p.W350L | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV101065258; called by muse, mutect2, varscan2
- ERV3-1 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99276037; called by muse, mutect2, varscan2
- EYA3 | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as COSV100870285; called by muse, mutect2, varscan2
- FAM124B | c.261C>A p.D87E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as COSV99706482; called by muse, mutect2, varscan2
- FAT1 | c.11326A>T p.R3776W | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV101499614; called by muse, mutect2
- FAT3 | c.2785G>A p.V929I | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV53143207; called by muse, mutect2, varscan2
- FAT3 | c.5703G>T p.E1901D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99970382; called by muse, mutect2, varscan2
- FAT4 | c.12931A>T p.I4311F | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV100629908; called by muse, mutect2, varscan2
- FBL | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1210775617, COSV99695409; called by muse, mutect2, varscan2
- FCRL4 | c.329C>A p.P110Q | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV99620363; called by muse, mutect2, varscan2
- FIGN | c.1009A>T p.S337C | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1343793790, COSV100292892; called by muse, mutect2, varscan2
- FLG2 | c.6274C>A p.Q2092K | Missense Mutation (SNP) | VAF 709/1388 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV101166153; called by muse, mutect2, varscan2
- FLRT2 | c.1888C>A p.P630T | Missense Mutation (SNP) | VAF 111/412 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100420932; called by muse, mutect2, varscan2
- FLT3 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV99610013; called by muse, mutect2, varscan2
- FLT3 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs376895552, COSV54050166; called by muse, mutect2, varscan2
- FMNL3 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99526879; called by muse, mutect2, varscan2
- FMR1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV99503739; called by muse, mutect2, varscan2
- FRMPD3 | c.2746C>A p.P916T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as COSV52190940; called by muse, mutect2, varscan2
- FSCB | c.1848G>T p.E616D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV100469775; called by muse, varscan2
- GALNT13 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV101224128; called by muse, mutect2, varscan2
- GLRA2 | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54342632; called by muse, mutect2, varscan2
- GMDS | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV101070632; called by muse, mutect2, varscan2
- GOPC | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99271307; called by muse, mutect2, varscan2
- GPR156 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs780287124, COSV100251674; called by muse, mutect2, varscan2
- GPR45 | c.538C>A p.P180T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV99307155; called by muse, mutect2, varscan2
- GRIK4 | c.975C>A p.S325R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101483364; called by muse, mutect2, varscan2
- GRIK4 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV101483730; called by muse, mutect2, varscan2
- GRIN2A | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.075); catalogued as COSV100410863; called by muse, mutect2, varscan2
- GRIN2C | c.2139C>A p.D713E | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV99501383; called by muse, mutect2, varscan2
- GRIP1 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs752025367, COSV99064732, COSV99670782; called by muse, mutect2, varscan2
- GTF2I | c.1342C>T p.L448F (on ENST00000573035 / NM_032999.4; = p.L407F on NM_001518.5) | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV100259880; called by muse, mutect2, varscan2
- H1-8 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100140325; called by muse, mutect2, varscan2
- HAAO | c.23G>T p.R8M | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV99685528; called by muse, mutect2, varscan2
- HCLS1 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100101066; called by muse, mutect2, varscan2
- HMBS | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.187); catalogued as COSV99598160; called by muse, mutect2, varscan2
- HOXC9 | c.275A>T p.Y92F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV100327624; called by muse, mutect2, varscan2
- HRH2 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as COSV99199895; called by muse, mutect2, varscan2
- ISLR | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV51434594, COSV99997520; called by muse, mutect2, varscan2
- ITGA1 | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99252047; called by muse, mutect2, varscan2
- ITGA8 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV100959635; called by muse, mutect2, varscan2
- JARID2 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 2/22 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1561904565; called by muse, mutect2
- KBTBD3 | c.1785G>T p.Q595H | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101595723; called by muse, mutect2, varscan2
- KCNAB1 | c.1135C>A p.P379T (on ENST00000490337 / NM_172160.3; = p.P368T on NM_003471.3) | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV100204948; called by muse, mutect2, varscan2
- KCND3 | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100138329, COSV56189460; called by muse, mutect2, varscan2
- KCNJ12 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100055999, COSV59165493; called by muse, varscan2
- KCNJ9 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs1017190452, COSV100927797; called by muse, mutect2, varscan2
- KDM4B | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99347251; called by muse, mutect2, varscan2
- KDM6A | c.4177G>C p.A1393P | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100938537; called by muse, mutect2, varscan2
- KIF6 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV54675077, COSV99760442; called by muse, mutect2, varscan2
- KPRP | c.443G>T p.C148F | Missense Mutation (SNP) | VAF 184/372 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as COSV100908779; called by muse, mutect2, varscan2
- KRT1 | c.90G>C p.R30S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.05); catalogued as COSV52866781, COSV99358970; called by muse, mutect2, varscan2
- KRT35 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV99877665, COSV99877896; called by muse, mutect2, varscan2
- KRTAP10-12 | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100555292; called by muse, mutect2, varscan2
- KRTAP19-6 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as COSV100473997, COSV61843732, COSV61844059; called by muse, mutect2, varscan2
- KRTAP4-12 | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs1176872098, COSV101224297; called by muse, mutect2, varscan2
- KRTAP9-3 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); catalogued as COSV100893228; called by muse, mutect2, varscan2
- LAMC2 | c.1133G>T p.W378L | Missense Mutation (SNP) | VAF 135/406 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99917869; called by muse, mutect2, varscan2
- LAMC2 | c.1134G>T p.W378C | Missense Mutation (SNP) | VAF 134/407 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99917870; called by muse, mutect2, varscan2
- LCE3D | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.419); catalogued as COSV64231211, COSV64231324; called by muse, mutect2, varscan2
- LILRB1 | c.389G>T p.G130V (on ENST00000427581; = p.G94V on NM_006669.6) | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533376327, COSV61120511; called by mutect2, varscan2
- LMBRD2 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV99683194; called by muse, mutect2, varscan2
- LRBA | c.5971C>T p.R1991C | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568717996, COSV100842036; called by muse, mutect2, varscan2
- LRP1B | c.7535C>A p.A2512D | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV101260114; called by muse, mutect2, varscan2
- LRRC30 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 77/287 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376967493, COSV101274452; called by muse, mutect2, varscan2
- LRRC47 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs1557642343, COSV65563113; called by muse, mutect2, varscan2
- LRTM1 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99836200; called by muse, mutect2, varscan2
- MADD | c.1928G>C p.S643T | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as COSV100211907; called by muse, mutect2, varscan2
- MAGEB2 | c.354G>T p.L118F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100975607; called by muse, mutect2, varscan2
- MAGI2 | c.3298C>A p.Q1100K | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV100836346; called by muse, mutect2, varscan2
- MAP3K4 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100815647; called by muse, mutect2, varscan2
- MARK4 | c.302A>C p.Q101P | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99488740; called by muse, mutect2, varscan2
- MAST2 | c.688T>G p.S230A | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV100788703; called by muse, mutect2, varscan2
- MBD5 | c.2050G>T p.G684* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as COSV101290246; called by muse, mutect2, varscan2
- MDGA2 | c.2297G>C p.G766A (on ENST00000399232 / NM_001113498.2; = p.G468A on NM_182830.4) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100638252; called by muse, mutect2, varscan2
- MDGA2 | c.2149C>T p.H717Y (on ENST00000399232 / NM_001113498.2; = p.H419Y on NM_182830.4) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.395); catalogued as COSV100638255, COSV62114688; called by muse, mutect2, varscan2
- MEF2D | c.1438A>T p.T480S | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100560293; called by muse, mutect2, varscan2
- MIOS | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.617); catalogued as COSV100402926; called by muse, mutect2, varscan2
- MMP24 | c.1714_1716del p.K572del | In Frame Del (DEL) | VAF 40/137 reads (29%) | catalogued as rs757961147; called by mutect2, pindel, varscan2
- MMP26 | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100332247; called by muse, mutect2, varscan2
- MOCS3 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV99724252, COSV99724485; called by muse, mutect2, varscan2
- MOG | c.525C>G p.F175L | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as COSV100973110; called by muse, mutect2, varscan2
- MPP2 | c.1303G>T p.V435F (on ENST00000461854 / NM_001278372.2; = p.V411F on NM_005374.5) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV99290784; called by muse, mutect2, varscan2
- MS4A8 | c.730A>C p.S244R | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV100282621; called by muse, mutect2, varscan2
- MSH3 | c.20C>A p.A7E | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.327); catalogued as COSV54153814; called by muse, mutect2, varscan2
- MT1H | c.94A>T p.S32C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100190078; called by muse, mutect2, varscan2
- MTG2 | c.524del p.C175Sfs*30 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as COSV63694220, COSV63694681; called by mutect2, pindel, varscan2
- MTUS1 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV100029943; called by muse, mutect2, varscan2
- MUC16 | c.39084G>T p.M13028I | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.969); catalogued as COSV101201333; called by muse, mutect2, varscan2
- MUC16 | c.36710C>T p.T12237I | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101201335; called by muse, mutect2, varscan2
- MUC16 | c.12335C>A p.T4112K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.148); catalogued as COSV101201336; called by muse, mutect2, varscan2
- MUC17 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 140/364 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100074840; called by muse, mutect2, varscan2
- MUC3A | c.8147T>A p.I2716N | Missense Mutation (SNP) | VAF 195/859 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs1192925342, COSV100115293; called by muse, mutect2, varscan2
- MYH13 | c.1201C>A p.L401M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52824956, COSV52832796; called by muse, mutect2, varscan2
- MYH13 | c.447G>C p.Q149H | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV52839510, COSV99355215; called by muse, mutect2, varscan2
- MYH4 | c.4691G>A p.R1564H | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs141756717; called by muse, mutect2, varscan2
- MYH6 | c.5291C>A p.A1764D | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100198180; called by muse, mutect2, varscan2
- MYO18B | c.2741G>A p.G914D | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100124959; called by muse, mutect2, varscan2
- NAP1L5 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as rs192140588, COSV52020999; called by muse, mutect2, varscan2
- NEB | c.2360C>A p.P787Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99427228; called by muse, mutect2, varscan2
- NEBL | c.2425G>C p.V809L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV101009260, COSV101009334; called by muse, mutect2, varscan2
- NEK5 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV100839291; called by muse, mutect2, varscan2
- NETO1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100198305, COSV100199614; called by muse, mutect2, varscan2
- NLGN4X | c.1960C>A p.H654N | Missense Mutation (SNP) | VAF 92/171 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV99323647; called by muse, mutect2, varscan2
- NLGN4X | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323651; called by muse, mutect2, varscan2
- NLGN4Y | c.1960C>A p.H654N | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100197101; called by muse, mutect2, varscan2
- NLRP10 | c.571del p.A191Pfs*16 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | catalogued as COSV60783058; called by mutect2, pindel, varscan2
- NLRP11 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as rs141720579; called by muse, mutect2, varscan2
- NPAP1 | c.2172C>G p.Y724* | Nonsense Mutation (SNP) | VAF 44/126 reads (35%) | catalogued as COSV100276076; called by muse, mutect2, varscan2
- NPHP3 | c.2089-2A>C p.X697_splice | Splice Site (SNP) | VAF 38/100 reads (38%) | catalogued as COSV100447297; called by muse, mutect2, varscan2
- NPHP3 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1448336864, COSV100447300; called by muse, mutect2, varscan2
- NRAP | c.1665G>C p.K555N (on ENST00000359988 / NM_001322945.2; = p.K520N on NM_006175.4) | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100748576; called by muse, mutect2, varscan2
- NRCAM | c.3913T>A p.*1305Kext*42 (on ENST00000379028 / NM_001371124.1; = p.*1184Kext*42 on NM_005010.4 and 21 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 94/218 reads (43%) | catalogued as COSV100695355; called by muse, mutect2, varscan2
- NRXN1 | c.3932C>A p.T1311N | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100640647, COSV60496917; called by muse, mutect2, varscan2
- NTM | c.401-2A>T p.X134_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100868147, COSV66196181; called by muse, mutect2, varscan2
- OASL | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV99984633; called by muse, mutect2, varscan2
- OR13D1 | c.477C>A p.C159* | Nonsense Mutation (SNP) | VAF 32/146 reads (22%) | catalogued as COSV100598747; called by muse, mutect2, varscan2
- OR1M1 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101447593; called by muse, mutect2, varscan2
- OR2AK2 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); catalogued as COSV100824309; called by muse, mutect2, varscan2
- OR2T34 | c.520T>G p.C174G | Missense Mutation (SNP) | VAF 54/302 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100170523; called by muse, mutect2, varscan2
- OR2W3 | c.282C>A p.Y94* | Nonsense Mutation (SNP) | VAF 90/216 reads (42%) | catalogued as COSV100831816; called by muse, mutect2, varscan2
- OR52J3 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100984929; called by muse, varscan2
- OR52K1 | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.169); catalogued as COSV100297740; called by muse, mutect2, varscan2
- OR5AR1 | c.507T>A p.C169* | Nonsense Mutation (SNP) | VAF 69/211 reads (33%) | catalogued as COSV100265765; called by muse, mutect2, varscan2
- OR5D16 | c.274A>G p.R92G | Missense Mutation (SNP) | VAF 121/361 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV101004126; called by muse, mutect2, varscan2
- OR5H15 | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as rs1298554471, COSV100736758, COSV62948871; called by muse, mutect2, varscan2
- OR6N2 | c.585C>A p.N195K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV100210449; called by muse, mutect2
- OR7D4 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100432856; called by muse, mutect2, varscan2
- OR8D4 | c.756T>A p.Y252* | Nonsense Mutation (SNP) | VAF 50/164 reads (30%) | catalogued as COSV100361932; called by muse, mutect2, varscan2
- OR8D4 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58430757, COSV58430785; called by muse, mutect2, varscan2
- PAPPA2 | c.1456C>A p.P486T | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV100867082; called by muse, mutect2, varscan2
- PAPPA2 | c.1457C>A p.P486Q | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV62777982, COSV62780998; called by muse, mutect2, varscan2
- PAPPA2 | c.4619A>T p.H1540L | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV100868544; called by muse, mutect2, varscan2
- PARD3B | c.3139G>T p.D1047Y (on ENST00000406610 / NM_001302769.2; = p.D978Y on NM_057177.7) | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.279); catalogued as COSV100594980; called by muse, mutect2, varscan2
- PCDH10 | c.689G>C p.R230P | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52095717, COSV99994373; called by muse, mutect2, varscan2
- PCDH15 | c.3994G>T p.G1332C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57396708; called by muse, mutect2, varscan2
- PCDHA1 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); catalogued as COSV65373699; called by muse, mutect2, varscan2
- PCDHB12 | c.2051A>T p.D684V | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV99507749; called by muse, mutect2, varscan2
- PCDHGA7 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.461); catalogued as rs1387934089, COSV53912777, COSV99545727; called by muse, varscan2
- PCMTD2 | c.306A>T p.L102= | Splice Region (SNP) | VAF 34/106 reads (32%) | catalogued as COSV100204309; called by muse, mutect2, varscan2
- PCTP | c.512-1G>T p.X171_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | catalogued as COSV99273884; called by muse, mutect2, varscan2
- PDCD6IP | c.1074G>C p.M358I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV100219127; called by muse, mutect2
- PDIA4 | c.1282T>A p.Y428N (on ENST00000286091 / NM_001371244.1; = p.Y427N on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99618846; called by muse, mutect2, varscan2
- PDP1 | c.1245G>T p.L415F | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99892816; called by muse, mutect2, varscan2
- PGBD2 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 158/280 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.297); catalogued as COSV100252220; called by muse, mutect2, varscan2
- PGK2 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100505662; called by muse, mutect2, varscan2
- PGM2 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101126634; called by muse, mutect2, varscan2
- PGRMC2 | c.401G>T p.S134I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs751047875, COSV99601062; called by muse, mutect2, varscan2
- PHF2 | c.2426C>A p.S809Y | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100823311; called by muse, mutect2, varscan2
- PI16 | c.736A>G p.T246A | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV101028799; called by muse, mutect2, varscan2
- PIK3CG | c.2895C>A p.F965L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100783124, COSV63247905; called by muse, mutect2, varscan2
- PLCD4 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.137); catalogued as COSV101335826; called by muse, mutect2, varscan2
- PLXNB1 | c.6339G>C p.Q2113H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1434161543, COSV56489519; called by muse, mutect2
- PLXNC1 | c.4216G>C p.V1406L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.229); catalogued as COSV99313706; called by muse, mutect2, varscan2
- PMM1 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as rs770052672, COSV99348249; called by muse, mutect2, varscan2
- PMS1 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV100575772, COSV59714562; called by muse, mutect2, varscan2
- PPARGC1A | c.737C>A p.S246* | Nonsense Mutation (SNP) | VAF 56/119 reads (47%) | catalogued as COSV99338532; called by muse, mutect2, varscan2
- PPP1R16B | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.524); catalogued as COSV100239946; called by muse, mutect2, varscan2
- PPP2R5A | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99806919; called by muse, mutect2
- PRDM2 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1557646262, COSV52444892; called by muse, mutect2, varscan2
- PRRC1 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 107/304 reads (35%) | SIFT tolerated, low confidence (0.57); PolyPhen possibly damaging (0.556); catalogued as COSV99688112; called by muse, mutect2, varscan2
- PRSS1 | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV100298417; called by muse, mutect2, varscan2
- PRSS21 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 66/480 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.065); catalogued as rs1199133170, COSV99135698; called by muse, mutect2, varscan2
- PTPRB | c.3613G>T p.E1205* | Nonsense Mutation (SNP) | VAF 33/92 reads (36%) | catalogued as COSV99718734; called by muse, mutect2, varscan2
- PTPRS | c.4106G>A p.S1369N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99512146; called by muse, mutect2, varscan2
- PXK | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.182); catalogued as COSV57086260, COSV57091753; called by muse, mutect2, varscan2
- RAB30 | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99475879; called by muse, mutect2, varscan2
- RAD54L2 | c.3397A>T p.M1133L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99621764; called by muse, mutect2, varscan2
- RANBP2 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99313087; called by muse, mutect2, varscan2
- RFX6 | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 57/99 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100264210; called by muse, mutect2, varscan2
- RFX6 | c.1364T>A p.L455H | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100264212; called by muse, mutect2, varscan2
- RGS9 | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 111/229 reads (48%) | catalogued as COSV99287934; called by muse, mutect2, varscan2
- RIMS2 | c.511A>G p.R171G | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.861); catalogued as COSV101267331; called by muse, mutect2, varscan2
- RNF14 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.578); catalogued as COSV100641285, COSV61662868; called by muse, mutect2, varscan2
- ROBO2 | c.2683+1G>T p.X895_splice | Splice Site (SNP) | VAF 34/108 reads (31%) | catalogued as COSV100169580; called by muse, mutect2, varscan2
- ROCK2 | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99837801; called by muse, mutect2, varscan2
- RP1L1 | c.2714C>A p.S905* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as rs1482383442, COSV101223557; called by muse, mutect2, varscan2
- RPS5 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs775466724, COSV52190502; called by muse, mutect2, varscan2
- RTEL1 | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100542779; called by muse, mutect2, varscan2
- RYK | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs55740278, COSV56063472; called by muse, mutect2, varscan2
- RYR1 | c.2921T>C p.V974A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100616800; called by muse, mutect2, varscan2
- RYR2 | c.913T>A p.Y305N | Missense Mutation (SNP) | VAF 124/260 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100772521; called by muse, mutect2, varscan2
- RYR2 | c.3042G>T p.Q1014H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV100772524; called by muse, mutect2, varscan2
- SCN10A | c.5294C>A p.S1765* | Nonsense Mutation (SNP) | VAF 19/124 reads (15%) | catalogued as COSV101479511, COSV71862542; called by muse, mutect2, varscan2
- SCN3A | c.3922G>T p.A1308S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51826054, COSV99328292; called by muse, mutect2, varscan2
- SCN4A | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV101438638; called by muse, mutect2, varscan2
- SCN5A | c.752C>A p.A251D | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV61120688; called by muse, mutect2, varscan2
- SEMA3E | c.386A>T p.H129L | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100319479; called by muse, mutect2, varscan2
- SETBP1 | c.487-1G>T p.X163_splice | Splice Site (SNP) | VAF 33/103 reads (32%) | catalogued as COSV99954687; called by muse, mutect2, varscan2
- SETBP1 | c.2296C>A p.Q766K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as COSV99954690; called by muse, mutect2, varscan2
- SETD4 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV100145739; called by muse, mutect2, varscan2
- SH3BP5 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV53743518; called by muse, mutect2, varscan2
- SHANK1 | c.2675G>T p.G892V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV99521886; called by muse, mutect2
- SHCBP1L | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as COSV100841079; called by muse, mutect2, varscan2
- SHPRH | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV99262624; called by muse, mutect2, varscan2
- SIGLEC12 | c.1468C>A p.L490M (on ENST00000291707 / NM_053003.4; = p.L372M on NM_033329.2) | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV99389566; called by muse, mutect2, varscan2
- SIM2 | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.217); catalogued as COSV99293564; called by muse, mutect2, varscan2
- SLC12A2 | c.1188+1G>T p.X396_splice | Splice Site (SNP) | VAF 54/138 reads (39%) | catalogued as COSV99321482; called by muse, mutect2, varscan2
- SLC20A2 | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs991432699, COSV100646208; called by muse, mutect2, varscan2
- SLC26A3 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100384913, COSV100385279; called by muse, mutect2, varscan2
- SLC29A4 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99786920; called by muse, mutect2, varscan2
- SLC39A12 | c.1316A>T p.H439L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.345); catalogued as rs994466090, COSV101070071, COSV101070128; called by muse, mutect2, varscan2
- SLC4A8 | c.1366G>T p.V456L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.271); catalogued as COSV100177442; called by muse, mutect2, varscan2
- SLC6A4 | c.1204+2T>A p.X402_splice | Splice Site (SNP) | VAF 20/126 reads (16%) | catalogued as COSV99911557; called by muse, mutect2, varscan2
- SLIT3 | c.3476C>A p.T1159N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100269500; called by muse, mutect2, varscan2
- SLIT3 | c.2535C>A p.D845E | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV100269502; called by muse, mutect2, varscan2
- SMOC2 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100635532; called by muse, mutect2, varscan2
- SNTG2 | c.987C>A p.Y329* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as rs761176950, COSV100424501, COSV57988290; called by muse, mutect2, varscan2
- SPO11 | c.712T>A p.C238S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV100625792; called by muse, mutect2, varscan2
- SPRED3 | c.640G>T p.G214W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as rs771562366, COSV100634277; called by mutect2, varscan2
- SRRM2 | c.6580C>T p.R2194W | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs780150943, COSV99241689; called by muse, mutect2, varscan2
- SSBP2 | c.63-1G>T p.X21_splice | Splice Site (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100284122; called by muse, mutect2, varscan2
- SVEP1 | c.5017C>A p.L1673M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV100990921; called by muse, mutect2
- SYNE1 | c.14266G>T p.V4756F (on ENST00000367255 / NM_182961.4; = p.V4685F on NM_033071.3) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99576357; called by muse, mutect2, varscan2
- SYTL3 | c.1035-2A>T p.X345_splice (on ENST00000611299 / NM_001242394.1; = p.X277_splice on NM_001009991.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 15/29 reads (52%) | catalogued as COSV99792519; called by muse, mutect2, varscan2
- TCTEX1D1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51075910, COSV99259372; called by muse, mutect2, varscan2
- TET1 | c.1357C>A p.Q453K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV101018823; called by muse, mutect2, varscan2
- TEX13B | c.455A>T p.H152L | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as rs1569476327, COSV100258489; called by muse, mutect2, varscan2
- TIAM2 | c.2287G>C p.G763R | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100019941, COSV59689136; called by muse, mutect2, varscan2
- TMEM132D | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV70600989, COSV70613616; called by muse, mutect2, varscan2
- TNRC6B | c.1867T>G p.W623G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100110393; called by muse, mutect2, varscan2
- TOPORS | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100745203; called by muse, mutect2, varscan2
- TRIO | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs767063550, COSV100710875; called by muse, mutect2, varscan2
- TRIP11 | c.4904G>T p.S1635I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99971104; called by muse, mutect2, varscan2
- TUBA3C | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV101262831; called by muse, mutect2, varscan2
- TUBA3C | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as rs768753886, COSV101262832, COSV101262855; called by muse, mutect2, varscan2
- TYRO3 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs148583498; called by muse, mutect2, varscan2
- UNC13C | c.3419A>T p.Q1140L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV99522385; called by muse, mutect2, varscan2
- UNC13C | c.4741G>T p.D1581Y | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV52865386; called by muse, mutect2, varscan2
- USP47 | c.1791G>C p.K597N (on ENST00000399455 / NM_001372095.1; = p.K509N on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV100359915; called by muse, mutect2, varscan2
- VEZF1 | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as COSV99365894; called by muse, mutect2, varscan2
- VN1R4 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV100237576; called by muse, mutect2, varscan2
- VPS13D | c.23G>T p.W8L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100693630; called by muse, mutect2, varscan2
- VPS13D | c.24G>T p.W8C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100693631; called by muse, mutect2, varscan2
- VPS39 | c.1256A>G p.Y419C (on ENST00000348544 / NM_001301138.2; = p.Y408C on NM_015289.5) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs988509940, COSV100529533; called by muse, mutect2, varscan2
- VPS41 | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV56071855; called by muse, mutect2, varscan2
- VWA5A | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV100795737; called by muse, mutect2
- VWA5A | c.246+1G>T p.X82_splice | Splice Site (SNP) | VAF 30/80 reads (38%) | catalogued as COSV100795738; called by muse, mutect2
- WAPL | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV100077245; called by muse, mutect2
- ZBED9 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 38/72 reads (53%) | catalogued as COSV101509370; called by muse, mutect2, varscan2
- ZC3H7B | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.059); catalogued as COSV100687721; called by muse, mutect2
- ZEB1 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV100314917; called by muse, mutect2, varscan2
- ZNF100 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99974299; called by muse, mutect2, varscan2
- ZNF100 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99974301; called by muse, mutect2, varscan2
- ZNF106 | c.3524C>A p.S1175Y | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV99783077; called by muse, mutect2, varscan2
- ZNF169 | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV100566357; called by muse, mutect2, varscan2
- ZNF221 | c.280A>T p.S94C | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99240911; called by muse, mutect2, varscan2
- ZNF251 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 59/132 reads (45%) | catalogued as COSV99478799; called by muse, mutect2, varscan2
- ZNF284 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101399075, COSV101399077; called by muse, mutect2, varscan2
- ZNF324B | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100351783; called by muse, mutect2, varscan2
- ZNF407 | c.4419G>T p.Q1473H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99996584; called by muse, mutect2, varscan2
- ZNF436 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs760327217, COSV100011299; called by muse, mutect2, varscan2
- ZNF445 | c.876G>T p.W292C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV101253874; called by muse, mutect2, varscan2
- ZNF473 | c.375G>T p.L125F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.183); catalogued as COSV99569061; called by muse, mutect2, varscan2
- ZNF518B | c.2799G>T p.L933F | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100456844; called by muse, mutect2, varscan2
- ZNF519 | c.1181A>G p.H394R | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101645591; called by muse, mutect2, varscan2
- ZNF521 | c.714G>C p.E238D | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100833237; called by muse, mutect2, varscan2
- ZNF567 | c.916G>T p.E306* (on ENST00000536254 / NM_001322913.1; = p.E275* on NM_152603.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100658968; called by muse, mutect2, varscan2
- ZNF57 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 41/110 reads (37%) | catalogued as COSV100183033; called by muse, mutect2, varscan2
- ZNF644 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61348696; called by muse, mutect2, varscan2
- ZNF786 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV100302982; called by muse, varscan2
- ZNF831 | c.1961C>A p.A654E | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV100926224; called by muse, mutect2, varscan2
- ZNF91 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100323385; called by muse, mutect2, varscan2
- ZPBP | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV99250391; called by muse, mutect2, varscan2
- ADAM15 | c.154del p.D52Ifs*18 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- ARHGEF11 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- CLCN2 | c.1987_1992del p.Q663_E664del | In Frame Del (DEL) | VAF 27/146 reads (18%) | called by mutect2, pindel, varscan2
- COX7A2L | c.218_219del p.V73Afs*10 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by pindel, varscan2
- DCLRE1A | c.1967_1974del p.L656Hfs*4 | Frame Shift Del (DEL) | VAF 61/219 reads (28%) | called by mutect2, pindel, varscan2
- DLGAP3 | c.1564G>C p.A522P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- FCGBP | c.7217_7222del p.Y2406_G2408delinsC | In Frame Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, varscan2
- FCGBP | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HAND2 | c.503dup p.A169Gfs*174 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | called by mutect2, pindel
- HTR5A | c.756del p.K253Nfs*84 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel
- IGHV1-24 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 85/370 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGHV3-66 | c.61del p.V21Cfs*10 | Frame Shift Del (DEL) | VAF 164/460 reads (36%) | called by pindel, varscan2
- IGKV2-30 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- KIAA1210 | c.2512_2520delinsG p.S838Vfs*5 | Frame Shift Del (DEL) | VAF 25/44 reads (57%) | called by pindel, varscan2*
- KIR2DL1 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 138/538 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); called by muse, varscan2
- MAGEB6 | c.1129del p.A377Pfs*19 | Frame Shift Del (DEL) | VAF 72/171 reads (42%) | called by mutect2, pindel, varscan2
- MYT1L | c.49del p.V17Ffs*64 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- NR4A3 | c.1759del p.L587Wfs*2 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- OR6C74 | c.833_834del p.S278Cfs*22 | Frame Shift Del (DEL) | VAF 19/147 reads (13%) | called by mutect2, pindel, varscan2
- PCDH11X | c.4001del p.P1334Rfs*29 | Frame Shift Del (DEL) | VAF 77/163 reads (47%) | called by mutect2, pindel, varscan2
- PCDHGA5 | c.1317del p.L440* | Frame Shift Del (DEL) | VAF 52/188 reads (28%) | called by mutect2, pindel, varscan2
- RYR2 | c.10572dup p.R3525* | Frame Shift Ins (INS) | VAF 170/444 reads (38%) | called by pindel, varscan2
- SLC39A6 | c.2069_2070dup p.A691Lfs*64 | Frame Shift Ins (INS) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- SPATA1 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TRBV29-1 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZFP36L1 | c.807dup p.G270Rfs*21 | Frame Shift Ins (INS) | VAF 56/165 reads (34%) | called by mutect2, pindel, varscan2
- ACBD5 | c.1359G>C p.L453= (on ENST00000375888 / NM_001352568.1; = p.L444= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as COSV101022620; called by muse, mutect2, varscan2
- ADAM2 | c.1725G>A p.V575= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV99697802; called by muse, mutect2, varscan2
- ADGRE1 | c.135C>A p.A45= | Silent (SNP) | VAF 71/213 reads (33%) | catalogued as COSV99165763; called by muse, mutect2, varscan2
- APBB2 | c.1773C>T p.H591= (on ENST00000295974 / NM_001166050.2; = p.H592= on NM_004307.2) | Silent (SNP) | VAF 71/144 reads (49%) | catalogued as rs566782894, COSV99923984; called by muse, mutect2, varscan2
- APOC3 | c.150G>T p.V50= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99369359; called by muse, mutect2, varscan2
- AREL1 | c.826C>T p.L276= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100707583, COSV100707645; called by muse, mutect2, varscan2
- ARHGEF37 | c.1050G>T p.L350= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV100382302; called by muse, mutect2, varscan2
- ARMCX2 | c.456A>C p.A152= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100168260; called by muse, mutect2, varscan2
- ATF7IP | c.381T>C p.A127= | Silent (SNP) | VAF 45/78 reads (58%) | catalogued as rs770876256, COSV99662067; called by muse, mutect2, varscan2
- AVPR1A | c.528G>T p.V176= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV100146902; called by muse, mutect2, varscan2
- CCKAR | c.555T>C p.F185= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV99810501; called by muse, mutect2, varscan2
- CD300LD | c.189C>T p.I63= | Silent (SNP) | VAF 125/288 reads (43%) | catalogued as rs1568023862, COSV100032614; called by muse, mutect2, varscan2
- CD33 | c.678C>G p.T226= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99220742; called by muse, mutect2, varscan2
- CDH7 | c.387C>A p.T129= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as COSV100543115; called by muse, mutect2, varscan2
- CDKN2B | c.348C>T p.P116= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs977430056, COSV99439648; called by muse, mutect2, varscan2
- CSMD3 | c.8820C>A p.A2940= (on ENST00000297405 / NM_001363185.1; = p.A2771= on NM_052900.3) | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as COSV99845883; called by muse, mutect2, varscan2
- CSNK2A2 | c.294G>T p.L98= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as COSV99345429; called by muse, mutect2, varscan2
- CTNNA1 | c.2055G>A p.A685= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs372902176; called by muse, mutect2, varscan2
- DCAF12L1 | c.48C>A p.V16= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100948432; called by muse, mutect2, varscan2
- DCHS1 | c.5841C>T p.T1947= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100202513; called by muse, mutect2
- DEFB127 | c.165C>T p.L55= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV101213884; called by muse, mutect2, varscan2
- DMGDH | c.339C>T p.I113= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99669449; called by muse, mutect2
- DMRTC2 | c.903G>T p.L301= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV99523478; called by muse, mutect2, varscan2
- DNAAF3 | c.993G>T p.G331= (on ENST00000524407 / NM_001256715.2; = p.G378= on NM_178837.4) | Silent (SNP) | VAF 47/138 reads (34%) | catalogued as COSV100788003, COSV61279872; called by muse, mutect2, varscan2
- DNMT3A | c.795G>T p.V265= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs753460571, COSV99264180; called by muse, mutect2, varscan2
- DPYSL5 | c.171G>T p.L57= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV99982738; called by muse, mutect2, varscan2
- DSP | c.7557G>T p.L2519= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV101131680; called by muse, mutect2, varscan2
- DST | c.2073C>T p.S691= (on ENST00000361203 / NM_001374722.1; = p.S365= on NM_001723.6) | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as COSV99759382; called by muse, mutect2, varscan2
- F13A1 | c.144C>G p.V48= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99343820; called by muse, mutect2, varscan2
- F5 | c.618G>T p.T206= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as COSV100889216; called by muse, mutect2
- FAM193B | c.1639T>C p.L547= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100286801; called by muse, mutect2, varscan2
- FAT1 | c.4146G>T p.V1382= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV101499615; called by muse, mutect2, varscan2
- FBN1 | c.5259A>G p.P1753= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1227515373, COSV100356256; called by muse, mutect2, varscan2
- FGF3 | c.249G>T p.V83= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV100490295; called by muse, mutect2, varscan2
- FUT9 | c.624G>A p.E208= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV100134203; called by muse, mutect2, varscan2
- GAP43 | c.357C>G p.A119= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100525910; called by muse, mutect2, varscan2
- HELB | c.933A>G p.T311= | Silent (SNP) | VAF 101/318 reads (32%) | catalogued as rs1320706029, COSV99922167; called by muse, mutect2, varscan2
- HOXB13 | c.672C>T p.S224= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as COSV99284928; called by muse, mutect2, varscan2
- IGHG1 | c.138G>T p.L46= | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- KCNA5 | c.510C>G p.P170= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99364154; called by muse, mutect2, varscan2
- KCNH8 | c.87C>T p.F29= | Silent (SNP) | VAF 32/206 reads (16%) | catalogued as COSV100110921; called by muse, mutect2, varscan2
- KCNK10 | c.123G>T p.P41= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as COSV56640940, COSV56642195; called by muse, mutect2, varscan2
- KCNQ2 | c.2442G>T p.L814= (on ENST00000359125 / NM_172107.4; = p.L786= on NM_004518.6) | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100610497; called by muse, mutect2, varscan2
- KIF1B | c.507T>C p.R169= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV99824063; called by muse, mutect2, varscan2
- KIR2DL1 | c.18C>A p.V6= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV99383587, COSV99383783; called by muse, mutect2
- LRFN2 | c.363G>T p.R121= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs879093591, COSV100599808; called by muse, mutect2, varscan2
- LRRC4B | c.1878C>G p.A626= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100976024, COSV65350140; called by muse, mutect2
- LRRK2 | c.2514A>G p.T838= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs1399769235, COSV100111029; called by muse, mutect2, varscan2
- LRTM1 | c.855C>T p.A285= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV99836199; called by muse, mutect2, varscan2
- LZTR1 | c.84G>T p.V28= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99302250; called by muse, mutect2
- MGAT3 | c.750G>T p.P250= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100361979; called by muse, mutect2, varscan2
- MLIP | c.1275G>A p.Q425= | Silent (SNP) | VAF 54/217 reads (25%) | catalogued as rs753292691, COSV99230348; called by muse, mutect2, varscan2
- MMP2 | c.1014C>T p.S338= | Silent (SNP) | VAF 76/163 reads (47%) | catalogued as COSV99528220; called by muse, mutect2, varscan2
- MMP25 | c.423C>T p.L141= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV100339597; called by muse, mutect2, varscan2
- MUC16 | c.10593C>T p.T3531= | Silent (SNP) | VAF 97/247 reads (39%) | catalogued as COSV101201337; called by muse, mutect2, varscan2
- NAPA | c.519G>T p.A173= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV54549949, COSV99645887; called by muse, mutect2, varscan2
- NDST4 | c.615C>A p.T205= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV99997680; called by muse, mutect2, varscan2
- NFIX | c.1161G>T p.P387= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV100666619; called by muse, mutect2, varscan2
- NLRP14 | c.1437C>T p.T479= | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as COSV100205369; called by muse, mutect2, varscan2
- NRXN3 | c.1840C>T p.L614= (on ENST00000335750 / NM_001330195.2; = p.L241= on NM_004796.6) | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV59746089; called by muse, mutect2
- ODF3L2 | c.789C>A p.R263= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99199156; called by muse, mutect2, varscan2
- OR10X1 | c.555C>T p.C185= | Silent (SNP) | VAF 13/146 reads (9%) | catalogued as COSV100936710; called by muse, mutect2
- OR2G3 | c.651C>A p.S217= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as COSV100180574; called by muse, mutect2, varscan2
- OR2M3 | c.381C>T p.C127= | Silent (SNP) | VAF 74/876 reads (8%) | catalogued as COSV101513508; called by muse, mutect2
- OR2T34 | c.627C>T p.I209= | Silent (SNP) | VAF 135/728 reads (19%) | catalogued as rs1265971463, COSV60900451, COSV60901057; called by muse, mutect2, varscan2
- OR3A2 | c.201C>G p.P67= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV101375078; called by muse, mutect2, varscan2
- OR4B1 | c.567C>T p.D189= | Silent (SNP) | VAF 23/186 reads (12%) | catalogued as COSV100535695; called by muse, mutect2, varscan2
- OR4C6 | c.435G>T p.G145= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as COSV100051811; called by muse, mutect2, varscan2
- OR51Q1 | c.396C>G p.L132= | Silent (SNP) | VAF 111/322 reads (34%) | catalogued as rs773437967, COSV100333066; called by muse, mutect2, varscan2
- OR5L2 | c.297G>A p.V99= | Silent (SNP) | VAF 39/196 reads (20%) | catalogued as COSV101004404; called by muse, mutect2, varscan2
- OR6C75 | c.909C>A p.V303= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs1270229922, COSV100595431, COSV58553058; called by muse, mutect2, varscan2
- OR6Q1 | c.309C>T p.S103= | Silent (SNP) | VAF 67/203 reads (33%) | catalogued as COSV100110450; called by muse, mutect2, varscan2
- OR7E24 | c.213C>T p.S71= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV71702358; called by muse, mutect2, varscan2
- PCDHB9 | c.1788G>T p.S596= | Silent (SNP) | VAF 32/105 reads (30%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.216G>T p.T72= | Silent (SNP) | VAF 42/129 reads (33%) | catalogued as COSV53946651, COSV99545726; called by muse, varscan2
- PCDHGB4 | c.1449C>A p.G483= | Silent (SNP) | VAF 23/162 reads (14%) | catalogued as COSV99545728; called by muse, mutect2, varscan2
- PDE6C | c.2100C>A p.A700= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV101008847; called by muse, mutect2, varscan2
- POLR1A | c.4557C>T p.T1519= | Silent (SNP) | VAF 57/145 reads (39%) | catalogued as rs746423557, COSV99808309; called by muse, mutect2, varscan2
- PRRX1 | c.534C>A p.P178= | Silent (SNP) | VAF 53/163 reads (33%) | catalogued as COSV53419162, COSV99510225; called by muse, mutect2, varscan2
- PTGER4 | c.1147C>A p.R383= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV100201739, COSV56721847; called by muse, mutect2, varscan2
- PTPRC | c.2994G>A p.E998= | Silent (SNP) | VAF 56/108 reads (52%) | catalogued as COSV100723093; called by muse, mutect2, varscan2
- R3HDML | c.558C>A p.T186= | Silent (SNP) | VAF 62/191 reads (32%) | catalogued as COSV53835419, COSV99407276; called by muse, mutect2, varscan2
- RADIL | c.1470G>T p.S490= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV101271607; called by muse, mutect2, varscan2
- RBM19 | c.81G>A p.T27= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as rs572718438, COSV55700579; called by muse, mutect2, varscan2
- RXFP3 | c.111G>A p.T37= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV100347146, COSV57504436; called by muse, mutect2, varscan2
- S100A7A | c.69T>A p.R23= | Silent (SNP) | VAF 166/345 reads (48%) | catalogued as COSV100241660; called by muse, mutect2, varscan2
- SF3A2 | c.681C>T p.P227= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV99678078; called by muse, mutect2, varscan2
- SFSWAP | c.66G>T p.G22= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV99906357; called by muse, mutect2, varscan2
- SLC16A9 | c.957A>T p.G319= | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as COSV101264463; called by muse, mutect2, varscan2
- SLC20A2 | c.924G>T p.R308= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV100646207, COSV60603247; called by muse, mutect2, varscan2
- SLC6A17 | c.180G>T p.R60= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs771431886, COSV100521496; called by muse, mutect2, varscan2
- SLIT1 | c.3324C>T p.L1108= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV99822362; called by muse, mutect2, varscan2
- SNX31 | c.156T>C p.F52= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV100310464; called by muse, mutect2, varscan2
- SORBS3 | c.1074C>T p.Y358= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV99531544; called by muse, mutect2, varscan2
- SREBF1 | c.2571C>T p.F857= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV99884902; called by muse, mutect2
- STX2 | c.495A>G p.E165= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV99893190; called by muse, mutect2, varscan2
- TAS1R2 | c.915C>T p.A305= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs777443351, COSV100946352, COSV64743709; called by muse, mutect2
- TBR1 | c.636C>T p.P212= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV101271523; called by muse, mutect2, varscan2
- TLDC2 | c.28C>A p.R10= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as rs757731171, COSV54115874, COSV99456032; called by muse, mutect2, varscan2
- TLR4 | c.2211G>T p.V737= (on ENST00000355622 / NM_138554.5; = p.V697= on NM_003266.4) | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100842846; called by muse, mutect2, varscan2
- TMEM174 | c.471G>T p.L157= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as rs773191648, COSV99703807; called by muse, mutect2, varscan2
- TMEM74B | c.606C>A p.G202= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV101121992; called by muse, mutect2, varscan2
- TRPA1 | c.2988C>A p.R996= | Silent (SNP) | VAF 42/82 reads (51%) | catalogued as COSV100085053; called by muse, mutect2, varscan2
- TUB | c.87C>A p.P29= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as COSV100539204; called by muse, mutect2, varscan2
- UBXN7 | c.1095G>C p.P365= | Silent (SNP) | VAF 54/144 reads (38%) | catalogued as COSV99581670; called by muse, mutect2, varscan2
- UGGT2 | c.4014G>A p.V1338= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100948651, COSV65077303; called by muse, mutect2, varscan2
- UGT1A8 | c.262C>A p.R88= | Silent (SNP) | VAF 74/225 reads (33%) | catalogued as rs368298766, COSV65078415; called by muse, mutect2, varscan2
- UGT2A1 | c.1491C>A p.V497= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV99684835; called by muse, mutect2, varscan2
- UNC5D | c.1482A>T p.G494= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV99778357; called by muse, mutect2, varscan2
- USH2A | c.10758C>A p.T3586= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs780888992, COSV100241496; called by muse, mutect2, varscan2
- USH2A | c.2649G>A p.E883= | Silent (SNP) | VAF 149/499 reads (30%) | catalogued as COSV100241502, COSV56351719; called by muse, mutect2, varscan2
- VASN | c.1911A>C p.A637= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99228074; called by muse, mutect2, varscan2
- XYLB | c.753A>G p.S251= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as rs974715231, COSV99264478; called by muse, mutect2, varscan2
- XYLT1 | c.1774C>A p.R592= | Silent (SNP) | VAF 109/214 reads (51%) | catalogued as COSV54479298, COSV99763118; called by muse, mutect2, varscan2
- ZNF516 | c.2823G>T p.A941= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs538615519, COSV101487357; called by muse, mutect2, varscan2
- AC073310.1 | n.350T>G | RNA (SNP) | VAF 52/286 reads (18%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.153G>T | RNA (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- CHRM2 | c.-47+33875C>A | Intron (SNP) | VAF 40/122 reads (33%) | catalogued as COSV100281264; called by muse, mutect2, varscan2
- CPE | c.307+6743G>T | Intron (SNP) | VAF 21/58 reads (36%) | catalogued as COSV101127490; called by muse, mutect2, varscan2
- LAPTM5 | c.*1C>A | 3'UTR (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99612651, COSV99612741; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85533del | Intron (DEL) | VAF 13/63 reads (21%) | called by pindel, varscan2
- MIR1302-3 | n.4T>A | RNA (SNP) | VAF 51/229 reads (22%) | called by muse, mutect2, varscan2
- MIR412 | n.66C>T | RNA (SNP) | VAF 41/163 reads (25%) | catalogued as rs534204576; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142670778 T>C | 3'Flank (SNP) | VAF 13/27 reads (48%) | catalogued as rs767081743; called by mutect2, varscan2
- OBSCN | c.11660-2595G>T | Intron (SNP) | VAF 73/209 reads (35%) | catalogued as COSV99483510; called by muse, mutect2, varscan2
- TALDO1 | c.*1C>T | 3'UTR (SNP) | VAF 11/97 reads (11%) | catalogued as rs145192861, COSV100032846; called by muse, mutect2, varscan2
